Somatic mutation profile of tumor specimen C3L-04848-01 (aliquot CPT0248410007) from CPTAC case C3L-04848, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.0 years (26,284 days).
Specimen C3L-04848-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2b0386a-8c59-40d8-aff3-b62c6c32d4c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04848-31 (Blood Derived Normal), aliquot CPT0248450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b71dc101-ab64-4a96-a5e1-402f9edfb87c

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Intron 4, Nonsense Mutation 3, Splice Site 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 68/523 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-2A>G p.X332_splice | Splice Site (SNP) | VAF 64/433 reads (15%) | hotspot (GDC flag); catalogued as rs867389695, CS159286, COSV52692098, COSV52692518, COSV53122371; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP39 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 83/561 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as rs1464815156; called by muse, mutect2, varscan2
- ATP13A4 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759539336, COSV55066550; called by muse, mutect2
- ATP8B1 | c.3261+1G>A p.X1087_splice | Splice Site (SNP) | VAF 23/380 reads (6%) | catalogued as COSV99377911; called by muse, mutect2
- BGN | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs150043639; called by muse, mutect2
- BICDL1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1476355880; called by muse, mutect2, varscan2
- CA5A | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs768389144; called by muse, mutect2, varscan2
- CBLL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs868368528, COSV60370252; called by muse, mutect2
- CCKBR | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58099194; called by muse, mutect2, varscan2
- CDKN2A | c.172del p.R58Efs*88 | Frame Shift Del (DEL) | VAF 93/799 reads (12%) | catalogued as CM940227, COSV58682666, COSV58721549, COSV99053472; called by mutect2, pindel, varscan2
- COL20A1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs749535969, COSV58920416, COSV99045407; called by muse, mutect2
- CSMD3 | c.8120G>A p.W2707* | Nonsense Mutation (SNP) | VAF 30/637 reads (5%) | catalogued as COSV52126876; called by muse, mutect2
- CTNNA2 | c.1051A>C p.N351H | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs1185995811, COSV63547281; called by muse, mutect2
- CWC25 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 20/304 reads (7%) | catalogued as rs760543725; called by muse, mutect2
- DCAF12L2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 40/754 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1338664181, COSV63580237, COSV63583223; called by muse, mutect2
- DPPA5 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV64875412; called by muse, mutect2
- DRP2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as rs755031248, COSV100871870, COSV65811879; called by muse, mutect2
- GRIA3 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99989435; called by muse, mutect2
- IGSF1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs767093474, COSV63836910; called by muse, mutect2
- MKRN3 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 84/726 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.375); catalogued as rs776896408; called by muse, mutect2, varscan2
- PRICKLE1 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 105/782 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1233536174, COSV58207605; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2838C>G p.I946M | Missense Mutation (SNP) | VAF 43/414 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs149659316; called by muse, mutect2, varscan2
- WDR90 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 62/583 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs778872146; called by muse, mutect2, varscan2
- ZNRF3 | c.622C>T p.R208C (on ENST00000544604 / NM_001206998.2; = p.R108C on NM_032173.3) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV60430961; called by muse, mutect2
- BCOR | c.5265G>A p.W1755* (on ENST00000378444 / NM_001123385.2; = p.W1721* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- CCDC73 | c.676A>C p.K226Q | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- CCR9 | c.943G>A p.V315I (on ENST00000357632 / NM_031200.3; = p.V303I on NM_006641.4) | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.264); called by muse, mutect2
- CIZ1 | c.719A>G p.K240R | Missense Mutation (SNP) | VAF 35/401 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.132); called by muse, mutect2
- LONRF3 | c.700G>C p.G234R | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.206); called by muse, mutect2
- MAGEB6B | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2
- NAGPA | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 60/1046 reads (6%) | PolyPhen probably damaging (0.995); called by muse, mutect2
- NIPBL | c.3859A>G p.N1287D | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- SLC25A33 | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2
- SLITRK1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.565); called by muse, mutect2
- ZNF597 | c.672C>G p.H224Q | Missense Mutation (SNP) | VAF 27/558 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2
- BCO1 | c.411G>A p.A137= | Silent (SNP) | VAF 44/992 reads (4%) | catalogued as rs1414090181; called by muse, mutect2
- C8orf76 | c.48G>A p.V16= | Silent (SNP) | VAF 29/379 reads (8%) | called by muse, mutect2
- CSTA | c.87A>G p.E29= | Silent (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2
- CYP1B1 | c.354G>A p.P118= | Silent (SNP) | VAF 99/718 reads (14%) | catalogued as COSV53192711; called by muse, mutect2, varscan2
- DNAH5 | c.7485G>A p.A2495= | Silent (SNP) | VAF 62/500 reads (12%) | catalogued as COSV54231710; called by muse, mutect2, varscan2
- GPS1 | c.1065C>T p.D355= | Silent (SNP) | VAF 41/452 reads (9%) | called by muse, mutect2
- PLCD1 | c.1314G>A p.K438= | Silent (SNP) | VAF 50/651 reads (8%) | called by muse, mutect2
- SAMD9L | c.261G>A p.P87= | Silent (SNP) | VAF 55/436 reads (13%) | catalogued as rs767681806; called by muse, mutect2, varscan2
- SLC4A2 | c.2004G>A p.G668= | Silent (SNP) | VAF 72/296 reads (24%) | catalogued as rs527345139; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2565T>A p.L855= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as rs1241803867; called by muse, varscan2
- SUPT3H | c.966G>T p.G322= (on ENST00000371460 / NM_181356.3; = p.G311= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/398 reads (4%) | called by muse, mutect2
- EIF5A | c.165+368G>A | Intron (SNP) | VAF 77/580 reads (13%) | catalogued as rs1427018323; called by muse, mutect2, varscan2
- HAND2 | c.*187G>A | 3'UTR (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- MAN2A2 | c.1944-13C>T | Intron (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- SLC35B1 | c.766+14C>G | Intron (SNP) | VAF 28/220 reads (13%) | catalogued as COSV53603009; called by muse, mutect2, varscan2
- ST3GAL3 | c.1084-29C>T | Intron (SNP) | VAF 98/843 reads (12%) | called by muse, mutect2, varscan2
